CCDI case PBCPTY — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Meningiomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/022261a6-5004-4bd5-afb8-a55a4ba8beaf

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Atypical meningioma: ICD-O-3 morphology code: 9539/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.2 years (453 days).

Biospecimens (3 samples)
- Sample 0DWVEP: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DWVF3: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DWVGS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
